Somatic mutation profile of tumor specimen HCM-CSHL-0141-C18-01A (aliquot HCM-CSHL-0141-C18-01A-11D-A77E-36) from HCMI case HCM-CSHL-0141-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 67.2 years (24,563 days).
Specimen HCM-CSHL-0141-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a887fcb4-6a10-453e-a6cc-32b52244300f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0141-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0141-C18-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8a5c309-ffee-49a6-ab8b-0310c5186dba

The open-access MAF lists 151 somatic variants for this specimen: 97 protein-altering or splice-affecting, 40 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 40, Nonsense Mutation 10, Intron 6, 3'UTR 3, Splice Region 2, RNA 2, 5'Flank 2, Frame Shift Ins 1, 3'Flank 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 82/203 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC018630.4 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | PolyPhen benign (0.018); catalogued as COSV101115506; called by muse, mutect2, varscan2
- ADGRV1 | c.2596C>T p.R866W | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.927); catalogued as rs200389929, COSV67983288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFF3 | c.2792C>T p.T931M | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs373018231; called by muse, mutect2, varscan2
- APC | c.2557G>T p.E853* | Nonsense Mutation (SNP) | VAF 39/202 reads (19%) | catalogued as COSV57347085, COSV57378777; called by muse, mutect2, varscan2
- APC | c.4087A>T p.K1363* | Nonsense Mutation (SNP) | VAF 53/130 reads (41%) | catalogued as COSV57337694, COSV57379285; called by muse, mutect2, varscan2
- ARMH4 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99957442; called by muse, mutect2, varscan2
- ATP2A1 | c.2944G>T p.E982* | Nonsense Mutation (SNP) | VAF 144/594 reads (24%) | catalogued as CM1411191, COSV62869021; called by muse, mutect2, varscan2
- ATP8B4 | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs749142543, COSV52710941; called by muse, mutect2, varscan2
- BMP7 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 194/345 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs371762840; called by muse, mutect2, varscan2
- BSN | c.8513C>T p.T2838M | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs546341531; called by muse, mutect2, varscan2
- CMYA5 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.08); catalogued as rs750047220; called by muse, mutect2, varscan2
- CNTNAP3 | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 98/484 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs769642592; called by muse, mutect2, varscan2
- CPEB3 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs767243674; called by muse, mutect2, varscan2
- DENND2A | c.1939G>A p.G647S | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs938952428, COSV52052029; called by muse, mutect2
- DGKD | c.2351G>A p.R784H (on ENST00000264057 / NM_152879.3; = p.R740H on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243657968; called by muse, mutect2, varscan2
- DISP3 | c.3370G>A p.E1124K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as rs1359184018, COSV53829251; called by muse, mutect2, varscan2
- DNAJC7 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs1555647599, COSV57269035; called by muse, mutect2, varscan2
- ELP5 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs762988971, COSV100598184; called by muse, varscan2
- FAM185A | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV68643357; called by muse, mutect2, varscan2
- FAM47A | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs756452001, COSV60493630; called by muse, mutect2, varscan2
- FOXA2 | c.1351C>T p.R451W (on ENST00000377115 / NM_153675.3; = p.R457W on NM_021784.5) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65796127; called by muse, mutect2, varscan2
- GTPBP2 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 86/379 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766935105; called by muse, mutect2, varscan2
- HCN2 | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs750444405; called by muse, mutect2, varscan2
- HLA-A | c.73+1G>C p.X25_splice | Splice Site (SNP) | VAF 22/71 reads (31%) | catalogued as COSV100954397; called by muse, mutect2, varscan2
- HOXD3 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs776045427; called by muse, mutect2, varscan2
- HSPG2 | c.7165G>A p.G2389S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs765181959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IKZF1 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 53/510 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.909); catalogued as rs779769920, COSV100498915; called by muse, mutect2, varscan2
- INVS | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs778036236, COSV52437949, COSV52447482; called by muse, mutect2, varscan2
- ITGBL1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs763790775; called by muse, mutect2, varscan2
- KCNA4 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs777488025, COSV100068823; called by muse, mutect2, varscan2
- KLF3 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs1472409063, COSV54711385; called by muse, mutect2, varscan2
- KY | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as rs563164206, COSV101414995; called by muse, mutect2, varscan2
- LBH | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1436120090; called by muse, mutect2, varscan2
- LRRTM1 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.165); catalogued as rs917603256, COSV99703058; called by muse, mutect2, varscan2
- MAPT | c.1622C>T p.T541M (on ENST00000262410 / NM_001377265.1; = p.T149M on NM_005910.5) | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs964226257, COSV52248065; called by muse, mutect2
- MARS1 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 69/306 reads (23%) | catalogued as rs150674269; called by muse, mutect2, varscan2
- NLRP14 | c.2179C>A p.H727N | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs1348554410; called by muse, mutect2, varscan2
- NLRP7 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs374600785; called by muse, mutect2, varscan2
- NPAS4 | c.1722G>T p.L574F | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1171011062, COSV60652272; called by muse, mutect2, varscan2
- NPHP3 | c.2795A>C p.N932T | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1560002446; called by muse, mutect2, varscan2
- NR5A2 | c.979C>T p.Q327* (on ENST00000367362 / NM_205860.3; = p.Q281* on NM_003822.5) | Nonsense Mutation (SNP) | VAF 56/367 reads (15%) | catalogued as rs1206691380, COSV52653498; called by muse, mutect2, varscan2
- OR52L1 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs769350807, COSV59988162; called by muse, mutect2, varscan2
- PCARE | c.3026G>A p.R1009H | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs200394246, COSV99045269; called by muse, mutect2, varscan2
- PCDHA6 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 180/885 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1262192253; called by muse, mutect2, varscan2
- PCDHA7 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 193/504 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1554134406, COSV65342182; called by muse, mutect2, varscan2
- PON3 | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55698045; called by muse, mutect2, varscan2
- PRSS38 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs147849633; called by muse, mutect2, varscan2
- PSTPIP1 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs377006780; called by muse, mutect2, varscan2
- RGL3 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs374802887; called by muse, mutect2, varscan2
- RIMS1 | c.3796C>A p.R1266S | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1359398086; called by muse, mutect2, varscan2
- RIPOR3 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1029273818; called by muse, mutect2, varscan2
- RNF123 | c.2261C>A p.A754E | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV59687160; called by muse, mutect2, varscan2
- ROBO1 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV101458641; called by muse, mutect2, varscan2
- SBK2 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs781195404; called by muse, mutect2, varscan2
- SCX | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 79/494 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs1248659763; called by muse, mutect2, varscan2
- SENP6 | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as rs560237458; called by muse, mutect2, varscan2
- SEZ6 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs548817464, COSV57982676; called by muse, mutect2, varscan2
- SLC4A9 | c.2444G>A p.G815D (on ENST00000507527 / NM_001258428.2; = p.G791D on NM_031467.3) | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769862352; called by muse, mutect2, varscan2
- SLC6A20 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs777908628, COSV100653839; called by muse, mutect2, varscan2
- SLC9A3 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 83/361 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327970675, COSV53804549; called by muse, mutect2, varscan2
- SLCO3A1 | c.94_96del p.K32del | In Frame Del (DEL) | VAF 14/104 reads (13%) | catalogued as rs1477752440; called by pindel, varscan2
- SMAD4 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1555685159, COSV61685150; ClinVar: uncertain significance; called by muse, varscan2
- STK11IP | c.2656C>T p.R886C | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs779471681, COSV55253251; called by muse, mutect2, varscan2
- STON1 | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs763696544; called by muse, mutect2, varscan2
- TLN1 | c.2746C>T p.R916C | Missense Mutation (SNP) | VAF 90/567 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs574795385, COSV59204317; called by muse, mutect2, varscan2
- TP63 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 59/195 reads (30%) | catalogued as rs147340040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIP12 | c.5680C>T p.R1894W | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1480116316; called by muse, mutect2
- USP29 | c.146G>T p.R49I | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs1568455663, COSV99572122; called by muse, mutect2, varscan2
- USP34 | c.7124G>A p.R2375H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs1008915384, COSV68406315; called by muse, mutect2, varscan2
- WSCD2 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 94/325 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV54579204, COSV99774807; called by muse, mutect2, varscan2
- ZIC5 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs769045432, COSV99940754; called by muse, mutect2, varscan2
- AMOT | c.1544T>C p.L515P (on ENST00000371959 / NM_001113490.1; = p.L106P on NM_133265.3) | Missense Mutation (SNP) | VAF 70/101 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- CCDC157 | c.1046-7G>T | Splice Region (SNP) | VAF 37/112 reads (33%) | called by muse, mutect2, varscan2
- COL12A1 | c.2510C>A p.A837E | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DBX2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC1I1 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EPB41L1 | c.1925A>G p.E642G | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ESD | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- FLG2 | c.3520G>T p.G1174C | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- FN1 | c.4015T>C p.S1339P | Missense Mutation (SNP) | VAF 52/354 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- HPS5 | c.1321C>T p.H441Y (on ENST00000349215 / NM_181507.2; = p.H327Y on NM_007216.4) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCNL1 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- LRFN5 | c.531T>A p.S177R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MLLT10 | c.2926C>T p.Q976* (on ENST00000307729 / NM_001195626.3; = p.Q992* on NM_004641.3) | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- NCAN | c.3277C>A p.H1093N | Missense Mutation (SNP) | VAF 74/402 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- OR51A7 | c.456C>A p.S152R | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OR52J3 | c.720C>A p.S240R | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PBX1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLPPR5 | c.307dup p.T103Nfs*54 | Frame Shift Ins (INS) | VAF 15/94 reads (16%) | called by mutect2, pindel, varscan2
- PTPRH | c.2462C>A p.A821E | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- RNF215 | c.671G>A p.C224Y | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STAB1 | c.4764G>A p.E1588= | Splice Region (SNP) | VAF 25/160 reads (16%) | called by muse, mutect2, varscan2
- TMTC1 | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIM49B | c.501C>A p.C167* | Nonsense Mutation (SNP) | VAF 52/204 reads (25%) | called by muse, mutect2, varscan2
- ZNF484 | c.706C>A p.Q236K | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ZNF528 | c.1682G>T p.C561F | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ADAM33 | c.1182C>T p.R394= | Silent (SNP) | VAF 33/189 reads (17%) | called by muse, mutect2, varscan2
- CD19 | c.1143G>A p.P381= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as rs757976340; called by muse, mutect2, varscan2
- CLU | c.705C>T p.Y235= | Silent (SNP) | VAF 120/400 reads (30%) | catalogued as rs751114860, COSV57067036; ClinVar: likely benign; called by muse, mutect2, varscan2
- COPS7B | c.433C>T p.L145= | Silent (SNP) | VAF 78/401 reads (19%) | called by muse, mutect2, varscan2
- DAB2IP | c.900G>A p.S300= (on ENST00000408936; = p.S272= on NM_032552.3) | Silent (SNP) | VAF 100/270 reads (37%) | catalogued as rs202119015, COSV52265730; called by muse, mutect2, varscan2
- EFCAB1 | c.351C>T p.D117= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs747636083, COSV50617990; called by muse, mutect2, varscan2
- FAM185A | c.963T>A p.L321= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- FAT4 | c.12018G>T p.T4006= | Silent (SNP) | VAF 34/137 reads (25%) | called by muse, mutect2, varscan2
- FLG | c.9522C>T p.S3174= | Silent (SNP) | VAF 19/306 reads (6%) | catalogued as rs1053812081; called by muse, mutect2
- FLG | c.8550C>T p.G2850= | Silent (SNP) | VAF 54/1403 reads (4%) | catalogued as rs376468454; called by muse, mutect2
- GAS2L3 | c.1620C>T p.S540= | Silent (SNP) | VAF 31/168 reads (18%) | catalogued as rs202229990; called by muse, mutect2, varscan2
- GRIN2A | c.2196C>T p.A732= | Silent (SNP) | VAF 53/133 reads (40%) | catalogued as rs748323416, COSV100411448; called by muse, mutect2, varscan2
- GTF2E1 | c.378C>T p.S126= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs1202594049; called by mutect2, varscan2
- IGF1R | c.3870G>A p.P1290= | Silent (SNP) | VAF 34/200 reads (17%) | catalogued as rs138888653, COSV51342228; called by muse, mutect2, varscan2
- KIF26B | c.642C>T p.Y214= | Silent (SNP) | VAF 39/200 reads (20%) | catalogued as rs751658390, COSV68572319; called by muse, mutect2, varscan2
- LAMA5 | c.11022C>T p.P3674= | Silent (SNP) | VAF 45/483 reads (9%) | catalogued as rs764906504, COSV99439113; called by muse, mutect2
- LARGE1 | c.1626C>T p.P542= | Silent (SNP) | VAF 130/319 reads (41%) | catalogued as rs775137166, COSV100506283; called by muse, mutect2, varscan2
- LRRTM1 | c.435G>A p.S145= | Silent (SNP) | VAF 56/293 reads (19%) | catalogued as rs761682948, COSV54445071, COSV99701623; called by muse, mutect2, varscan2
- MORN1 | c.297C>T p.G99= | Silent (SNP) | VAF 62/285 reads (22%) | catalogued as rs779763554; called by muse, mutect2, varscan2
- NCCRP1 | c.48C>T p.A16= | Silent (SNP) | VAF 23/535 reads (4%) | catalogued as rs987698596; called by muse, mutect2
- OR2H1 | c.279G>T p.L93= | Silent (SNP) | VAF 40/225 reads (18%) | called by muse, mutect2, varscan2
- OR4D1 | c.441C>T p.A147= | Silent (SNP) | VAF 43/270 reads (16%) | catalogued as rs372813872; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.915C>T p.R305= (on ENST00000259318 / NM_001136562.3; = p.R536= on NM_007203.5) | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as rs770245489, COSV52178299; called by muse, mutect2, varscan2
- PALM3 | c.879C>A p.G293= (on ENST00000340790; = p.G308= on NM_001145028.2) | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- PCDHB12 | c.1992C>T p.D664= | Silent (SNP) | VAF 47/307 reads (15%) | catalogued as rs534329232; called by mutect2, varscan2
- PPFIA2 | c.792C>T p.T264= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs377170926, COSV61061855; called by muse, mutect2, varscan2
- PPP1R13B | c.990G>A p.T330= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as rs376013196; called by muse, mutect2, varscan2
- QRICH2 | c.3954G>A p.E1318= | Silent (SNP) | VAF 41/186 reads (22%) | called by muse, mutect2, varscan2
- RPL3 | c.594C>T p.R198= | Silent (SNP) | VAF 62/390 reads (16%) | catalogued as rs368072771; called by muse, mutect2, varscan2
- RYR1 | c.11940G>C p.A3980= | Silent (SNP) | VAF 109/450 reads (24%) | catalogued as rs750022861, COSV62098494; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAC3D1 | c.18G>A p.L6= | Silent (SNP) | VAF 60/241 reads (25%) | called by muse, mutect2, varscan2
- SLC4A1 | c.1755C>T p.A585= | Silent (SNP) | VAF 184/444 reads (41%) | called by muse, mutect2, varscan2
- SLC6A13 | c.1203G>A p.A401= | Silent (SNP) | VAF 38/197 reads (19%) | catalogued as rs140923338; called by muse, mutect2, varscan2
- SPAG8 | c.312C>T p.H104= | Silent (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2
- SSTR5 | c.684G>T p.V228= | Silent (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- SUPT16H | c.1545A>T p.P515= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- TMEM266 | c.837G>A p.A279= | Silent (SNP) | VAF 22/154 reads (14%) | catalogued as rs1254929804; called by muse, mutect2, varscan2
- TTC21A | c.969C>T p.I323= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs369704736; called by muse, mutect2, varscan2
- UGT1A1 | c.21C>T p.G7= | Silent (SNP) | VAF 61/201 reads (30%) | catalogued as rs780253764, COSV100530873; called by muse, mutect2, varscan2
- ZNF280D | c.2646G>A p.K882= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as rs1273219633; called by muse, mutect2, varscan2
- CLU | c.*591G>T | 3'UTR (SNP) | VAF 29/196 reads (15%) | called by muse, mutect2, varscan2
- CYP4F3 | c.199-1738G>T | Intron (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415213 G>A | 5'Flank (SNP) | VAF 53/142 reads (37%) | called by muse, mutect2, varscan2
- DCHS2 | n.7267C>A | RNA (SNP) | VAF 55/142 reads (39%) | called by muse, mutect2, varscan2
- ERBB2 | c.1022-83G>A | Intron (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- GPSM1 | chr9:136327035 C>T | 5'Flank (SNP) | VAF 7/58 reads (12%) | catalogued as rs1345141139; called by muse, mutect2, varscan2
- KCNQ1 | c.*148G>A | 3'UTR (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- LINC01583 | n.1403C>G | RNA (SNP) | VAF 15/132 reads (11%) | called by muse, mutect2, varscan2
- MGAM2 | c.5138-302G>A | Intron (SNP) | VAF 26/123 reads (21%) | catalogued as rs904149283; called by muse, mutect2, varscan2
- NAV3 | c.2024-13005C>T | Intron (SNP) | VAF 19/197 reads (10%) | catalogued as rs867606698, COSV57106168; called by muse, mutect2
- PCDHB6 | chr5:141157703 G>T | 3'Flank (SNP) | VAF 177/869 reads (20%) | called by muse, mutect2, varscan2
- PDE7B | c.711+118C>T | Intron (SNP) | VAF 23/151 reads (15%) | catalogued as rs750908439, COSV100367475; called by muse, mutect2, varscan2
- SCRIB | c.643-28C>T | Intron (SNP) | VAF 35/235 reads (15%) | catalogued as rs559575765, COSV100252686; called by muse, mutect2, varscan2
- TP53TG3D | c.*187G>A | 3'UTR (SNP) | VAF 84/647 reads (13%) | called by muse, mutect2, varscan2
